Somatic mutation profile of tumor specimen HCM-BROD-0831-C71-01A (aliquot HCM-BROD-0831-C71-01A-11D-A85K-36) from HCMI case HCM-BROD-0831-C71, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 78.1 years (28,542 days).
Specimen HCM-BROD-0831-C71-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 64f8eec7-79ed-42bb-8f43-43772cbfacf2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0831-C71-10A (Blood Derived Normal), aliquot HCM-BROD-0831-C71-10A-01D-A85K-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ebe9cfc5-7a6d-48f3-bd8c-1e32b0c2c188

The open-access MAF lists 112 somatic variants for this specimen: 70 protein-altering or splice-affecting, 36 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 65, Silent 36, Intron 4, Nonsense Mutation 2, 3'UTR 2, Frame Shift Del 1, Splice Site 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AHNAK2 | c.7982C>T p.S2661L | Missense Mutation (SNP) | VAF 188/268 reads (70%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as rs746854104; called by muse, varscan2
- APOB | c.11809G>A p.E3937K | Missense Mutation (SNP) | VAF 92/235 reads (39%) | SIFT tolerated (0.17); PolyPhen benign (0.009); catalogued as rs766656064, COSV51925162; called by muse, mutect2, varscan2
- BRCC3 | c.830C>T p.S277L | Missense Mutation (SNP) | VAF 178/420 reads (42%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.99); catalogued as rs782796649; called by muse, mutect2, varscan2
- BRDT | c.2530G>T p.E844* | Nonsense Mutation (SNP) | VAF 122/348 reads (35%) | catalogued as COSV62863840; called by muse, varscan2
- CAPN9 | c.212G>A p.G71E | Missense Mutation (SNP) | VAF 17/245 reads (7%) | SIFT tolerated (0.75); PolyPhen possibly damaging (0.878); catalogued as COSV55239941; called by muse, mutect2
- CDH6 | c.551C>T p.T184M | Missense Mutation (SNP) | VAF 94/317 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.753); catalogued as rs764565018, COSV54078937; called by muse, mutect2, varscan2
- CDS2 | c.1285C>T p.R429W | Missense Mutation (SNP) | VAF 198/469 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.453); catalogued as rs904904787; called by muse, mutect2, varscan2
- CPS1 | c.4198G>A p.A1400T | Missense Mutation (SNP) | VAF 138/391 reads (35%) | SIFT deleterious (0.05); PolyPhen benign (0.116); catalogued as rs779382562; called by muse, mutect2, varscan2
- CRNN | c.62C>T p.T21M | Missense Mutation (SNP) | VAF 146/396 reads (37%) | SIFT tolerated (0.12); PolyPhen benign (0.085); catalogued as rs201339909; called by muse, mutect2, varscan2
- FANCD2 | c.1015G>A p.G339S | Missense Mutation (SNP) | VAF 125/358 reads (35%) | SIFT tolerated (0.79); PolyPhen benign (0.003); catalogued as rs144332316; called by muse, mutect2, varscan2
- FLT4 | c.2431G>C p.G811R | Missense Mutation (SNP) | VAF 180/473 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV56121969; called by muse, mutect2, varscan2
- GORASP2 | c.112G>C p.D38H | Missense Mutation (SNP) | VAF 107/270 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1434726317, COSV52204086; called by muse, mutect2, varscan2
- IGSF10 | c.3052G>A p.G1018R | Missense Mutation (SNP) | VAF 175/454 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as rs372539492; called by muse, mutect2, varscan2
- IRS1 | c.1505C>T p.T502M | Missense Mutation (SNP) | VAF 214/505 reads (42%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as rs201965582; called by muse, mutect2, varscan2
- KIAA1958 | c.1949C>T p.S650F | Missense Mutation (SNP) | VAF 171/534 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.852); catalogued as COSV61722697; called by muse, mutect2, varscan2
- KIAA2012 | c.3287G>A p.R1096Q | Missense Mutation (SNP) | VAF 134/373 reads (36%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.464); catalogued as rs749854414; called by muse, mutect2, varscan2
- KSR2 | c.1451G>A p.R484Q | Missense Mutation (SNP) | VAF 163/386 reads (42%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.608); catalogued as rs779973325, COSV56673180; called by muse, mutect2, varscan2
- MAN1A1 | c.123G>T p.K41N | Missense Mutation (SNP) | VAF 49/428 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.662); catalogued as rs1234558925; called by muse, mutect2, varscan2
- MAP7D3 | c.698C>G p.S233W | Missense Mutation (SNP) | VAF 139/369 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV60171013; called by muse, mutect2, varscan2
- MRGPRX4 | c.13G>A p.V5I | Missense Mutation (SNP) | VAF 109/222 reads (49%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs758613833, COSV100049711; called by muse, mutect2, varscan2
- MROH2B | c.3043G>A p.G1015S | Missense Mutation (SNP) | VAF 162/353 reads (46%) | SIFT tolerated (0.26); PolyPhen benign (0.144); catalogued as rs1211364496, COSV68181233, COSV68191170; called by muse, mutect2, varscan2
- MUC2 | c.1121C>T p.A374V | Missense Mutation (SNP) | VAF 125/323 reads (39%) | SIFT tolerated (0.46); catalogued as rs751277029; called by muse, varscan2
- NCR3LG1 | c.397G>A p.G133R | Missense Mutation (SNP) | VAF 120/302 reads (40%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.651); catalogued as COSV100164430; called by muse, mutect2, varscan2
- NIBAN1 | c.589C>T p.H197Y | Missense Mutation (SNP) | VAF 99/248 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as rs1429868422; called by muse, mutect2, varscan2
- OR2G2 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 182/442 reads (41%) | SIFT tolerated (0.59); PolyPhen benign (0.021); catalogued as rs760919741, COSV60739255; called by muse, mutect2
- OR52E2 | c.128G>T p.G43V | Missense Mutation (SNP) | VAF 168/351 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV58612873; called by muse, mutect2, varscan2
- PCDHA13 | c.1313C>T p.T438M | Missense Mutation (SNP) | VAF 303/685 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.928); catalogued as rs144119560, COSV56499067; called by muse, mutect2, varscan2
- PCLO | c.15201A>T p.K5067N | Missense Mutation (SNP) | VAF 148/508 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61664320; called by muse, mutect2, varscan2
- PFKFB1 | c.1081C>T p.R361C | Missense Mutation (SNP) | VAF 130/306 reads (42%) | PolyPhen probably damaging (0.917); catalogued as COSV66628219; called by muse, mutect2, varscan2
- PIGT | c.349C>A p.Q117K | Missense Mutation (SNP) | VAF 134/320 reads (42%) | SIFT tolerated (0.39); PolyPhen benign (0.081); catalogued as COSV99648938, COSV99649101; called by muse, mutect2, varscan2
- PLPPR4 | c.1253C>T p.P418L | Missense Mutation (SNP) | VAF 179/454 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100926975; called by muse, mutect2, varscan2
- SEC16A | c.3271G>A p.G1091R | Missense Mutation (SNP) | VAF 207/561 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.06); catalogued as rs1192420124; called by muse, mutect2, varscan2
- SETD1A | c.3712C>T p.R1238C | Missense Mutation (SNP) | VAF 260/628 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.799); catalogued as rs774783241; called by muse, mutect2, varscan2
- TAF4B | c.2117G>A p.R706Q | Missense Mutation (SNP) | VAF 78/241 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs536777986, COSV52310932; called by muse, mutect2, varscan2
- TTN | c.12119T>C p.I4040T (on ENST00000591111; = p.I3994T on NM_003319.4) | Missense Mutation (SNP) | VAF 201/456 reads (44%) | catalogued as rs770591157; called by muse, mutect2, varscan2
- ZMAT4 | c.205G>A p.D69N | Missense Mutation (SNP) | VAF 134/323 reads (41%) | SIFT tolerated (0.44); PolyPhen benign (0.001); catalogued as rs776568390, COSV52690119; called by muse, mutect2, varscan2
- ATP2B2 | c.1118C>A p.S373Y (on ENST00000352432; = p.S339Y on NM_001683.5) | Missense Mutation (SNP) | VAF 219/541 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CCP110 | c.2499C>G p.F833L | Missense Mutation (SNP) | VAF 85/192 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- CLIP2 | c.950G>A p.S317N | Missense Mutation (SNP) | VAF 228/768 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- COL6A1 | c.2015A>G p.E672G | Missense Mutation (SNP) | VAF 16/497 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.193); called by muse, mutect2
- DENND2A | c.2369A>G p.Y790C | Missense Mutation (SNP) | VAF 163/574 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GK2 | c.439A>C p.T147P | Missense Mutation (SNP) | VAF 158/424 reads (37%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.63); called by muse, mutect2, varscan2
- HS6ST2 | c.587C>T p.S196L | Missense Mutation (SNP) | VAF 314/737 reads (43%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.228); called by muse, mutect2, varscan2
- IGFN1 | c.841A>G p.R281G | Missense Mutation (SNP) | VAF 197/461 reads (43%) | SIFT tolerated (0.34); PolyPhen benign (0); called by muse, mutect2, varscan2
- IPO5 | c.304C>T p.Q102* | Nonsense Mutation (SNP) | VAF 138/369 reads (37%) | called by muse, mutect2, varscan2
- KRT77 | c.1514G>A p.S505N | Missense Mutation (SNP) | VAF 289/661 reads (44%) | SIFT tolerated (0.11); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- MRPS5 | c.265T>G p.F89V | Missense Mutation (SNP) | VAF 111/263 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- NCOA6 | c.212dup p.N71Kfs*60 | Frame Shift Ins (INS) | VAF 95/255 reads (37%) | called by mutect2, pindel, varscan2
- NF2 | c.1501A>T p.I501F | Missense Mutation (SNP) | VAF 165/224 reads (74%) | SIFT tolerated (0.05); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- NWD1 | c.1046C>T p.A349V | Missense Mutation (SNP) | VAF 219/555 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.666); called by muse, mutect2, varscan2
- PBRM1 | c.1094_1095del p.R365Lfs*2 | Frame Shift Del (DEL) | VAF 36/368 reads (10%) | called by mutect2, pindel
- PCDH7 | c.1919T>G p.M640R | Missense Mutation (SNP) | VAF 151/399 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.514); called by muse, mutect2, varscan2
- PNMA6E | c.1472T>C p.M491T (on ENST00000445091 / NM_001367770.1; = p.M213T on NM_001351293.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/716 reads (3%) | SIFT tolerated (1); PolyPhen benign (0.412); called by muse, mutect2
- POLG | c.893A>C p.H298P | Missense Mutation (SNP) | VAF 24/409 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- PPP5C | c.680T>C p.V227A | Missense Mutation (SNP) | VAF 129/346 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); called by muse, mutect2, varscan2
- PRKAG1 | c.455G>A p.R152K | Missense Mutation (SNP) | VAF 152/370 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RALGAPA1 | c.3775C>T p.P1259S | Missense Mutation (SNP) | VAF 128/172 reads (74%) | SIFT tolerated (0.55); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SCT | c.64C>A p.P22T | Missense Mutation (SNP) | VAF 159/359 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.39); called by muse, mutect2, varscan2
- SLC4A1AP | c.914A>T p.K305M | Missense Mutation (SNP) | VAF 190/473 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- SMG6 | c.1004G>A p.G335E | Missense Mutation (SNP) | VAF 198/406 reads (49%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.251); called by muse, mutect2, varscan2
- SPATA31A7 | c.370G>C p.G124R | Missense Mutation (SNP) | VAF 268/1245 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- TMPRSS15 | c.1457T>A p.I486N | Missense Mutation (SNP) | VAF 28/302 reads (9%) | SIFT tolerated (0.31); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- TTN | c.65642A>T p.E21881V (on ENST00000591111; = p.E14457V on NM_003319.4) | Missense Mutation (SNP) | VAF 168/435 reads (39%) | PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- TXNRD3 | c.14C>T p.P5L | Missense Mutation (SNP) | VAF 176/398 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.856); called by muse, mutect2, varscan2
- UPF3B | c.1322T>A p.L441H (on ENST00000276201 / NM_080632.3; = p.L428H on NM_023010.3) | Missense Mutation (SNP) | VAF 148/357 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- VPS13D | c.4367C>T p.P1456L | Missense Mutation (SNP) | VAF 157/362 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- XIRP2 | c.5870A>G p.D1957G (on ENST00000628543; = p.D2132G on NM_152381.6) | Missense Mutation (SNP) | VAF 140/332 reads (42%) | SIFT tolerated (0.22); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZFYVE26 | c.4674+1G>A p.X1558_splice | Splice Site (SNP) | VAF 101/147 reads (69%) | called by muse, mutect2, varscan2
- ZNF462 | c.7147G>A p.E2383K | Missense Mutation (SNP) | VAF 121/198 reads (61%) | SIFT deleterious (0); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- ZNF735 | c.361G>A p.E121K | Missense Mutation (SNP) | VAF 133/427 reads (31%) | SIFT tolerated (0.27); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- ADGRL3 | c.4719G>A p.P1573= (on ENST00000506720 / NM_001322402.2; = p.P1462= on NM_015236.6) | Silent (SNP) | VAF 99/264 reads (38%) | catalogued as rs771284076, COSV72229236; called by muse, mutect2, varscan2
- ALK | c.2265C>T p.H755= | Silent (SNP) | VAF 183/471 reads (39%) | catalogued as rs770603023, COSV66565155; ClinVar: likely benign; called by muse, mutect2, varscan2
- AMDHD1 | c.891G>A p.T297= | Silent (SNP) | VAF 141/333 reads (42%) | catalogued as rs547323409; called by muse, mutect2, varscan2
- AMOT | c.1725A>C p.R575= (on ENST00000371959 / NM_001113490.1; = p.R166= on NM_133265.3) | Silent (SNP) | VAF 211/519 reads (41%) | called by muse, mutect2, varscan2
- CCDC63 | c.1093C>A p.R365= | Silent (SNP) | VAF 30/392 reads (8%) | called by muse, mutect2
- CRISP3 | c.75C>A p.T25= (on ENST00000371159 / NM_001368123.1; = p.T17= on NM_001190986.2) | Silent (SNP) | VAF 212/516 reads (41%) | catalogued as COSV53823148; called by muse, mutect2, varscan2
- CTAGE1 | c.303C>T p.C101= | Silent (SNP) | VAF 185/438 reads (42%) | catalogued as rs1474288797, COSV66942850; called by muse, mutect2, varscan2
- DENND1C | c.507C>T p.S169= | Silent (SNP) | VAF 210/526 reads (40%) | called by muse, mutect2, varscan2
- DNAH7 | c.10407C>T p.P3469= | Silent (SNP) | VAF 176/438 reads (40%) | called by muse, varscan2
- DRP2 | c.2553G>A p.T851= | Silent (SNP) | VAF 268/664 reads (40%) | catalogued as rs1203536460; called by muse, mutect2, varscan2
- EHD4 | c.546C>T p.A182= | Silent (SNP) | VAF 86/326 reads (26%) | catalogued as rs145101817; called by muse, mutect2, varscan2
- EXOC3L1 | c.99G>A p.A33= | Silent (SNP) | VAF 232/566 reads (41%) | catalogued as rs146322735; called by muse, mutect2, varscan2
- FAM47B | c.1752C>T p.D584= | Silent (SNP) | VAF 250/583 reads (43%) | catalogued as COSV61452643; called by muse, mutect2, varscan2
- FASN | c.6279G>A p.E2093= | Silent (SNP) | VAF 57/528 reads (11%) | catalogued as rs1205548680; called by muse, mutect2, varscan2
- GOLGA6L22 | c.1890G>A p.E630= | Silent (SNP) | VAF 131/484 reads (27%) | called by muse, mutect2, varscan2
- GRM3 | c.810C>G p.R270= | Silent (SNP) | VAF 246/900 reads (27%) | catalogued as COSV64480463, COSV64480794; called by muse, mutect2, varscan2
- GSG1L2 | c.585T>C p.D195= | Silent (SNP) | VAF 122/325 reads (38%) | catalogued as rs1318006194; called by muse, mutect2, varscan2
- H4-16 | c.168G>A p.R56= | Silent (SNP) | VAF 202/447 reads (45%) | called by muse, mutect2, varscan2
- KCNJ3 | c.213C>A p.L71= | Silent (SNP) | VAF 158/418 reads (38%) | catalogued as COSV54543707; called by mutect2, varscan2
- KLF14 | c.18G>A p.A6= | Silent (SNP) | VAF 133/476 reads (28%) | called by muse, mutect2, varscan2
- LCN15 | c.36G>A p.L12= | Silent (SNP) | VAF 174/464 reads (38%) | called by muse, mutect2, varscan2
- LILRB5 | c.57C>T p.T19= | Silent (SNP) | VAF 192/505 reads (38%) | catalogued as COSV60257064; called by muse, varscan2
- LRP2 | c.381C>T p.C127= | Silent (SNP) | VAF 116/303 reads (38%) | called by muse, mutect2, varscan2
- MARCHF4 | c.858G>T p.V286= | Silent (SNP) | VAF 101/245 reads (41%) | called by muse, mutect2, varscan2
- OR2T8 | c.837C>T p.F279= | Silent (SNP) | VAF 70/211 reads (33%) | catalogued as COSV100178020; called by muse, mutect2, varscan2
- PPEF1 | c.438C>G p.T146= | Silent (SNP) | VAF 130/327 reads (40%) | called by muse, mutect2, varscan2
- PRR23A | c.654G>A p.P218= | Silent (SNP) | VAF 182/464 reads (39%) | catalogued as rs1217185242; called by muse, mutect2, varscan2
- PTPN3 | c.2277A>T p.P759= | Silent (SNP) | VAF 152/369 reads (41%) | called by muse, mutect2, varscan2
- ROS1 | c.1077G>A p.L359= | Silent (SNP) | VAF 145/361 reads (40%) | called by muse, mutect2, varscan2
- SACS | c.8832A>G p.L2944= | Silent (SNP) | VAF 32/390 reads (8%) | called by muse, mutect2
- SEMA7A | c.1827C>A p.G609= | Silent (SNP) | VAF 242/605 reads (40%) | catalogued as COSV56089705; called by muse, mutect2, varscan2
- SPEF1 | c.696G>A p.E232= | Silent (SNP) | VAF 118/321 reads (37%) | called by muse, mutect2, varscan2
- SPTA1 | c.6273C>T p.S2091= | Silent (SNP) | VAF 178/469 reads (38%) | catalogued as COSV63750195; called by muse, mutect2, varscan2
- TPCN2 | c.330C>T p.D110= | Silent (SNP) | VAF 228/545 reads (42%) | catalogued as rs199768477, COSV53733691; called by muse, mutect2, varscan2
- TRHDE | c.12C>T p.D4= | Silent (SNP) | VAF 240/556 reads (43%) | catalogued as COSV99671752; called by muse, mutect2
- TRPC7 | c.2526C>T p.S842= | Silent (SNP) | VAF 182/428 reads (43%) | catalogued as rs371371913; called by muse, mutect2, varscan2
- GABRD | c.1060-82C>T | Intron (SNP) | VAF 40/954 reads (4%) | catalogued as rs950334423; called by muse, mutect2
- HS6ST2 | c.948-40039A>C | Intron (SNP) | VAF 147/342 reads (43%) | called by muse, varscan2
- KCNQ1 | c.1394-18116C>T | Intron (SNP) | VAF 141/320 reads (44%) | catalogued as rs770361058; called by muse, mutect2, varscan2
- PEG10 | c.*589A>G | 3'UTR (SNP) | VAF 133/482 reads (28%) | called by muse, mutect2, varscan2
- TBXA2R | c.*718G>C | 3'UTR (SNP) | VAF 83/202 reads (41%) | called by muse, mutect2, varscan2
- TTN | c.33340+384G>A | Intron (SNP) | VAF 95/235 reads (40%) | catalogued as rs894171947, COSV60086368; called by muse, mutect2, varscan2
